Somatic mutation profile of tumor specimen ALCH-B2CV-TTP1-A (aliquot ALCH-B2CV-TTP1-A-1-0-D-A776-36) from ALCHEMIST case ALCH-B2CV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.6 years (20,659 days).
Specimen ALCH-B2CV-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8476aa9a-cce1-4606-ae1d-c573f1d8031b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2CV-NB1-A (Blood Derived Normal), aliquot ALCH-B2CV-NB1-A-1-0-D-A776-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/87f365ba-d49c-4701-9b1d-09eca24934f3

The open-access MAF lists 83 somatic variants for this specimen: 64 protein-altering or splice-affecting, 13 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 13, Nonsense Mutation 5, 3'UTR 2, RNA 2, 5'UTR 1, Intron 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 444/929 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.455del p.P152Rfs*18 | Frame Shift Del (DEL) | VAF 33/120 reads (28%) | catalogued as rs730882019, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABI2 | c.61G>C p.D21H | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV53694391; called by muse, varscan2
- AHI1 | c.1933C>T p.R645C | Missense Mutation (SNP) | VAF 15/253 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs1291908829; called by muse, mutect2
- AICDA | c.159C>T p.N53= | Splice Region (SNP) | VAF 52/305 reads (17%) | catalogued as COSV57565481; called by muse, mutect2, varscan2
- CALCB | c.143T>C p.L48P | Missense Mutation (SNP) | VAF 93/376 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs1264892328, COSV100158138, COSV60834929; called by muse, mutect2, varscan2
- CBARP | c.2102G>A p.R701H | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs774067812, COSV53068402; called by muse, mutect2, varscan2
- CDIPT | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 18/287 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265958830; called by muse, mutect2
- COL14A1 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 10/247 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1248831275, COSV52855638; called by muse, mutect2
- DMXL1 | c.4802C>T p.S1601F | Missense Mutation (SNP) | VAF 65/273 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV60716190; called by muse, mutect2, varscan2
- FMR1 | c.1848G>C p.E616D | Missense Mutation (SNP) | VAF 15/364 reads (4%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.009); catalogued as COSV54422655; called by muse, mutect2
- FYCO1 | c.4329C>G p.I1443M | Missense Mutation (SNP) | VAF 28/633 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as rs764209557; called by muse, mutect2
- IL3RA | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1318699562, COSV58431359, COSV58432095; called by muse, mutect2
- ITGA10 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs782159627, COSV100995068; called by muse, mutect2
- LAMC2 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 15/493 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1186804472, COSV51454211, COSV99917150; called by muse, mutect2
- LAMC3 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs1232269520; called by muse, mutect2, varscan2
- MAP7D2 | c.165G>C p.Q55H | Missense Mutation (SNP) | VAF 19/463 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65529793; called by muse, mutect2
- PCDHB1 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 7/185 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1554267169, COSV60630142; called by muse, mutect2
- SETD2 | c.4465A>G p.K1489E | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100338432; called by muse, mutect2
- SFTPA2 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 26/504 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.398); catalogued as rs890914935; called by muse, mutect2
- SNRNP200 | c.2548C>G p.L850V | Missense Mutation (SNP) | VAF 28/601 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV60487252; called by muse, mutect2
- TTN | c.88600C>T p.R29534C (on ENST00000591111; = p.R22110C on NM_003319.4) | Missense Mutation (SNP) | VAF 64/368 reads (17%) | PolyPhen benign (0.409); catalogued as rs766346925, COSV100592009; called by muse, mutect2, varscan2
- ZNF80 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 24/335 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.319); catalogued as rs781010667; called by muse, mutect2
- AMPD2 | c.1440C>G p.Y480* | Nonsense Mutation (SNP) | VAF 30/162 reads (19%) | called by muse, mutect2, varscan2
- ANK2 | c.1716G>C p.K572N | Missense Mutation (SNP) | VAF 19/621 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATRX | c.1384G>C p.A462P | Missense Mutation (SNP) | VAF 19/275 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.039); called by muse, mutect2
- CHST6 | c.1180C>T p.R394* | Nonsense Mutation (SNP) | VAF 13/198 reads (7%) | called by muse, mutect2
- CNDP1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- COL1A2 | c.1370G>A p.G457E | Missense Mutation (SNP) | VAF 15/546 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DONSON | c.572G>C p.R191T | Missense Mutation (SNP) | VAF 19/471 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- DZIP1L | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 35/204 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FANCE | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 18/603 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2
- GPC4 | c.754A>G p.I252V | Missense Mutation (SNP) | VAF 13/276 reads (5%) | SIFT tolerated (0.84); PolyPhen benign (0.027); called by muse, mutect2
- IGKV2D-24 | c.232A>T p.N78Y | Missense Mutation (SNP) | VAF 95/227 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- JADE1 | c.2194C>G p.Q732E | Missense Mutation (SNP) | VAF 11/273 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- JAKMIP2 | c.905A>G p.N302S | Missense Mutation (SNP) | VAF 36/292 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- KRT13 | c.904G>C p.E302Q | Missense Mutation (SNP) | VAF 31/632 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2
- LAS1L | c.235A>T p.R79W | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- LBHD1 | c.775G>A p.E259K (on ENST00000431002 / NM_001367940.1; = p.E233K on NM_024099.3) | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.237); called by muse, mutect2
- LTBP3 | c.3293T>G p.V1098G | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- M1AP | c.315C>G p.F105L | Missense Mutation (SNP) | VAF 14/493 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.085); called by muse, mutect2
- MAGEB5 | c.225A>C p.Q75H | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MAT1A | c.222G>A p.M74I | Missense Mutation (SNP) | VAF 35/659 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- MX2 | c.970A>G p.I324V | Missense Mutation (SNP) | VAF 71/409 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- MYCBP2 | c.3416C>T p.A1139V (on ENST00000357337; = p.A1177V on NM_015057.5) | Missense Mutation (SNP) | VAF 53/213 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MYOF | c.425G>C p.G142A | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.013); called by muse, mutect2
- NEMF | c.2314G>T p.E772* | Nonsense Mutation (SNP) | VAF 12/206 reads (6%) | called by muse, mutect2
- OAS3 | c.595T>G p.L199V | Missense Mutation (SNP) | VAF 58/436 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- OR4A15 | c.374G>A p.C125Y | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.275); called by muse, mutect2
- OR4C15 | c.334A>T p.M112L (on ENST00000314644; = p.M58L on NM_001001920.2) | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.272); called by muse, mutect2
- PDSS1 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.137); called by muse, mutect2
- POLG | c.1567G>A p.D523N | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.023); called by muse, mutect2
- RTN3 | c.848C>G p.S283* (on ENST00000377819 / NM_001265589.2; = p.S264* on NM_201428.3) | Nonsense Mutation (SNP) | VAF 10/238 reads (4%) | called by muse, mutect2
- RUNX2 | c.1150G>A p.E384K (on ENST00000371438; = p.E362K on NM_001015051.3) | Missense Mutation (SNP) | VAF 24/680 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.437); called by muse, mutect2
- SBNO2 | c.2531C>T p.S844F | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPOCD1 | c.2922C>A p.F974L | Missense Mutation (SNP) | VAF 11/214 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2
- SURF6 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.5); called by muse, mutect2
- TMEM98 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 13/287 reads (5%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.849); called by muse, mutect2
- TPCN1 | c.483G>A p.W161* | Nonsense Mutation (SNP) | VAF 11/314 reads (4%) | called by muse, mutect2
- UNC13A | c.126G>T p.Q42H | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- USP41 | c.520G>T p.D174Y | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- YARS2 | c.1103G>C p.R368T | Missense Mutation (SNP) | VAF 38/310 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- ZBTB5 | c.969G>C p.E323D | Missense Mutation (SNP) | VAF 9/192 reads (5%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2
- ZNF292 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.682); called by muse, mutect2
- C22orf42 | c.201G>A p.P67= | Silent (SNP) | VAF 42/210 reads (20%) | catalogued as rs752035598; called by muse, mutect2, varscan2
- CCDC166 | c.72G>A p.E24= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs897297701; called by muse, mutect2
- CRY1 | c.942C>T p.I314= | Silent (SNP) | VAF 18/459 reads (4%) | catalogued as COSV50482845; called by muse, mutect2
- DLG2 | c.2058G>A p.L686= | Silent (SNP) | VAF 17/307 reads (6%) | called by muse, mutect2
- FANCF | c.69C>T p.V23= | Silent (SNP) | VAF 77/440 reads (18%) | catalogued as rs987030810; called by muse, mutect2, varscan2
- KNDC1 | c.246C>T p.P82= | Silent (SNP) | VAF 25/209 reads (12%) | catalogued as rs773066267; called by muse, mutect2, varscan2
- LRRC66 | c.1179G>T p.L393= | Silent (SNP) | VAF 12/282 reads (4%) | called by muse, mutect2
- PTPRK | c.2175C>T p.C725= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as rs750995140, COSV100950316; called by muse, mutect2, varscan2
- SHROOM1 | c.2253C>G p.L751= (on ENST00000378679 / NM_001172700.2; = p.L746= on NM_133456.2) | Silent (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2
- SLC26A7 | c.1722G>A p.L574= | Silent (SNP) | VAF 16/316 reads (5%) | catalogued as COSV52591342; called by muse, mutect2
- TMEM215 | c.6G>T p.R2= | Silent (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- TSSK6 | c.318C>T p.R106= | Silent (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2
- ZNF660 | c.168G>C p.G56= | Silent (SNP) | VAF 9/185 reads (5%) | called by muse, mutect2
- AC103796.1 | n.148-24900A>G | Intron (SNP) | VAF 22/574 reads (4%) | catalogued as rs1439064007; called by muse, mutect2
- AC136604.1 | n.191T>C | RNA (SNP) | VAF 20/170 reads (12%) | called by muse, mutect2, varscan2
- GVINP1 | n.3855T>C | RNA (SNP) | VAF 42/229 reads (18%) | catalogued as rs1353291518; called by muse, mutect2, varscan2
- MOG | c.*251G>T | 3'UTR (SNP) | VAF 90/468 reads (19%) | called by muse, mutect2, varscan2
- PPP2R2B | c.-31C>G | 5'UTR (SNP) | VAF 28/456 reads (6%) | called by muse, mutect2
- TTC23L | c.*21G>A | 3'UTR (SNP) | VAF 27/520 reads (5%) | catalogued as rs766063455; called by muse, mutect2
